Somatic mutation profile of tumor specimen TCGA-38-4625-01A (aliquot TCGA-38-4625-01A-01D-1553-08) from TCGA case TCGA-38-4625, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.4 years (24,241 days).
Specimen TCGA-38-4625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9777e902-9957-4186-b9f5-a710e40cd1b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4625-11A (Solid Tissue Normal), aliquot TCGA-38-4625-11A-01D-1553-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/878e541b-61a0-443f-8921-78d76525f72c

The open-access MAF lists 625 somatic variants for this specimen: 478 protein-altering or splice-affecting, 137 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 406, Silent 137, Nonsense Mutation 36, Splice Site 15, Frame Shift Del 8, Splice Region 5, Intron 4, 3'Flank 3, Translation Start Site 3, In Frame Del 2, RNA 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM014696, COSV58688961, COSV58702489, COSV58705912; called by muse, mutect2, varscan2
- FMO3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs72549320, CM035641, COSV63007629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 99/284 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519909, COSV61068437; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1072G>T p.G358* | Nonsense Mutation (SNP) | VAF 83/173 reads (48%) | catalogued as rs121912576, COSV61685645; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AANAT | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1251921910; called by muse, mutect2
- ABCA9 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60623808; called by muse, mutect2, varscan2
- ABCC12 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60916173; called by muse, mutect2, varscan2
- ABCG4 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV56644851; called by muse, mutect2, varscan2
- ACTC1 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.551); catalogued as COSV51760267; called by muse, mutect2, varscan2
- ADAMTS1 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99535915; called by muse, mutect2, varscan2
- ADAMTS6 | c.2291A>T p.D764V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1481005633, COSV66862443; called by muse, mutect2, varscan2
- ADAR | c.3066G>T p.W1022C | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52718408; called by muse, mutect2, varscan2
- ADCY1 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52038918; called by muse, mutect2, varscan2
- ADCY10 | c.2774G>T p.R925M | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV63242984; called by muse, mutect2, varscan2
- ADGRB3 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65408442; called by muse, mutect2
- AGAP2 | c.1683G>A p.E561= (on ENST00000547588 / NM_001122772.2; = p.E225= on NM_014770.4) | Splice Region (SNP) | VAF 78/523 reads (15%) | catalogued as COSV57728167, COSV57730210, COSV57731479; called by muse, mutect2, varscan2
- AGBL1 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV66847459, COSV66865761; called by muse, mutect2, varscan2
- AIM2 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1464104598, COSV63700933; called by muse, mutect2, varscan2
- AKAP11 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 62/206 reads (30%) | catalogued as COSV50299067; called by muse, mutect2, varscan2
- ANK1 | c.4607G>T p.R1536L | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs767213092, COSV55881712, COSV55888592; called by muse, mutect2, varscan2
- ANK1 | c.3601G>T p.A1201S | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs139513895, COSV55888615; called by muse, mutect2, varscan2
- ANO5 | c.2273G>T p.R758L | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61088034; called by muse, mutect2, varscan2
- APAF1 | c.2485A>T p.S829C (on ENST00000551964 / NM_181861.2; = p.S818C on NM_013229.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV59666157; called by muse, mutect2, varscan2
- APOB | c.5022G>C p.E1674D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV51944609; called by muse, mutect2, varscan2
- ARAP3 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV53352652; called by muse, mutect2, varscan2
- ARHGEF18 | c.1129+1G>T p.X377_splice (on ENST00000359920 / NM_001130955.2; = p.X273_splice on NM_015318.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100149127; called by muse, mutect2, varscan2
- ARID3C | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99426778; called by muse, mutect2, varscan2
- ARL4D | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60721706; called by muse, mutect2, varscan2
- ARMH3 | c.626C>G p.A209G | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV64236833; called by muse, mutect2, varscan2
- ASCC3 | c.4522A>C p.M1508L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64978117; called by muse, mutect2, varscan2
- ASTN2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 30/214 reads (14%) | catalogued as COSV57799341; called by muse, mutect2, varscan2
- ATP9B | c.2759A>C p.H920P | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56956768; called by muse, mutect2, varscan2
- ATXN7L2 | c.1955G>C p.G652A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.033); catalogued as COSV60204098, COSV60205468, COSV60205506; called by muse, mutect2, varscan2
- BBS9 | c.1822G>C p.D608H (on ENST00000242067 / NM_001348036.1; = p.D568H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54178034; called by muse, mutect2, varscan2
- BCO2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs1309701978, COSV63064243; called by muse, mutect2, varscan2
- BDP1 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV62432921; called by muse, mutect2, varscan2
- BEND2 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1383842796, COSV66216553; called by muse, mutect2, varscan2
- BIRC6 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70203224; called by muse, mutect2, varscan2
- BLK | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52054218; called by muse, mutect2, varscan2
- BRINP1 | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56298380, COSV56307010; called by muse, mutect2, varscan2
- C10orf90 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV52959497; called by muse, mutect2, varscan2
- C2orf78 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV68518496; called by muse, mutect2, varscan2
- C8orf34 | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV61388081; called by muse, mutect2, varscan2
- CACNG6 | c.745G>T p.G249W (on ENST00000252729 / NM_145814.1; = p.G178W on NM_031897.2) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV53167448; called by muse, mutect2, varscan2
- CAMTA1 | c.4775A>G p.Q1592R | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV57915201; called by muse, mutect2, varscan2
- CASP10 | c.1195C>T p.Q399* (on ENST00000272879 / NM_032974.5; = p.Q356* on NM_001230.5) | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV53779648; called by muse, mutect2, varscan2
- CCDC148 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs760807168, COSV51766260; called by muse, mutect2, varscan2
- CCDC73 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58796947; called by muse, mutect2, varscan2
- CCDC80 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52818667; called by muse, mutect2, varscan2
- CCNB3 | c.1794G>T p.M598I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52076982; called by muse, mutect2, varscan2
- CD163L1 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV58016523, COSV58020762; called by muse, mutect2, varscan2
- CDH18 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56942993; called by muse, mutect2, varscan2
- CDH7 | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59890056; called by muse, mutect2, varscan2
- CDK8 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV67421959; called by muse, mutect2, varscan2
- CEP126 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV54828210; called by muse, mutect2, varscan2
- CFAP54 | c.6452A>C p.Y2151S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as rs779690503, COSV61573616; called by muse, mutect2, varscan2
- CHAT | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.08); catalogued as COSV100339850; called by muse, mutect2, varscan2
- CHD4 | c.1765G>T p.D589Y (on ENST00000357008 / NM_001363606.2; = p.D602Y on NM_001273.5) | Missense Mutation (SNP) | VAF 185/453 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58906668; called by muse, mutect2, varscan2
- CHGB | c.1128G>C p.Q376H | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs753516907, COSV66761120; called by muse, mutect2, varscan2
- CLCA1 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV52329443, COSV52332065; called by muse, mutect2, varscan2
- CLCN3 | c.2263C>G p.L755V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.106); catalogued as COSV61627166, COSV61627952; called by muse, mutect2, varscan2
- CLEC4F | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV55480501; called by muse, mutect2, varscan2
- CLSTN2 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71723265; called by muse, mutect2, varscan2
- CLVS2 | c.703A>C p.S235R | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV51566344; called by muse, mutect2, varscan2
- CMTR2 | c.1156G>T p.G386* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV57604302; called by muse, mutect2, varscan2
- CNMD | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 96/281 reads (34%) | catalogued as rs772962330, COSV65033649; called by muse, mutect2, varscan2
- COL12A1 | c.2734G>T p.V912F | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as COSV59402002, COSV59409865; called by muse, mutect2, varscan2
- COL14A1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52861956; called by muse, mutect2, varscan2
- COL27A1 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs779531434, COSV61928894; called by muse, mutect2, varscan2
- COL28A1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68083504; called by muse, mutect2, varscan2
- COL4A2 | c.2059G>C p.G687R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64631205; called by muse, mutect2, varscan2
- COL4A5 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1052281498, COSV60366888; called by muse, mutect2, varscan2
- COPG1 | c.1450C>A p.H484N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59115582; called by muse, mutect2, varscan2
- CR1 | c.4195C>A p.P1399T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887420; called by muse, mutect2, varscan2
- CR1 | c.4196C>A p.P1399Q | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887421; called by muse, mutect2, varscan2
- CSMD1 | c.3176G>T p.G1059V (on ENST00000520002; = p.G1058V on NM_033225.6) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59277987, COSV59353066; called by muse, mutect2, varscan2
- CSMD2 | c.8057C>A p.S2686Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.756); catalogued as COSV53936952, COSV53968577; called by muse, mutect2, varscan2
- CSMD3 | c.6893G>T p.G2298V (on ENST00000297405 / NM_001363185.1; = p.G2194V on NM_052900.3) | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189454471, COSV52252143; called by muse, mutect2, varscan2
- CSMD3 | c.1652A>C p.N551T (on ENST00000297405 / NM_001363185.1; = p.N447T on NM_052900.3) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); catalogued as COSV52252160; called by muse, mutect2
- CST4 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54150083; called by muse, mutect2, varscan2
- CTCFL | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 144/586 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV54776897; called by muse, varscan2
- CTSF | c.998G>T p.C333F | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59749783; called by muse, mutect2, varscan2
- CYP24A1 | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV53775755; called by muse, mutect2, varscan2
- CYP4F12 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV61175348; called by muse, mutect2, varscan2
- DAB1 | c.1313A>T p.K438M (on ENST00000371231; = p.K405M on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV64695682; called by muse, mutect2
- DACH2 | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV64178405; called by muse, mutect2, varscan2
- DACH2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV64178420; called by muse, mutect2, varscan2
- DBX1 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99910124; called by muse, mutect2
- DBX1 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV99910127; called by muse, mutect2
- DCAF8 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs767163915, COSV58785025; called by muse, mutect2
- DCHS1 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55039396; called by muse, mutect2, varscan2
- DCLK3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 65/256 reads (25%) | catalogued as COSV101374154, COSV69364070; called by mutect2, varscan2
- DDIAS | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV61271318; called by muse, mutect2, varscan2
- DDX10 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 43/302 reads (14%) | catalogued as COSV59437556; called by muse, mutect2, varscan2
- DIP2B | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99998032; called by muse, mutect2
- DIPK2B | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV67641067; called by muse, mutect2, varscan2
- DLX5 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV56032182, COSV99756271; called by muse, mutect2
- DLX5 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99756276; called by muse, mutect2
- DNAH10 | c.2882T>A p.L961Q (on ENST00000409039; = p.L900Q on NM_207437.3) | Missense Mutation (SNP) | VAF 108/650 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101292332, COSV68997884; called by muse, mutect2, varscan2
- DNAH2 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs191721380, COSV66722944; called by muse, mutect2, varscan2
- DNM1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100359580; called by muse, mutect2, varscan2
- DOCK4 | c.4140G>T p.L1380F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV70240488, COSV70241758; called by muse, varscan2
- DOCK9 | c.5323C>A p.R1775S (on ENST00000376460 / NM_001366676.2; = p.R1776S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV59637199; called by muse, mutect2, varscan2
- DOP1A | c.3031G>T p.V1011L | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV52714150; called by muse, mutect2, varscan2
- DPP6 | c.676C>A p.H226N (on ENST00000377770 / NM_001364500.2; = p.H164N on NM_001936.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100123568; called by muse, mutect2
- DPP6 | c.1606T>A p.C536S (on ENST00000377770 / NM_001364500.2; = p.C474S on NM_001936.5) | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59631403; called by muse, mutect2, varscan2
- DSCAM | c.2182+1G>T p.X728_splice | Splice Site (SNP) | VAF 39/111 reads (35%) | catalogued as COSV68031893; called by muse, mutect2, varscan2
- DSE | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV59066061; called by muse, mutect2, varscan2
- DSG1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV57132936, COSV57137702; called by muse, mutect2, varscan2
- DTNA | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV52015758; called by muse, mutect2, varscan2
- DYSF | c.3218C>A p.S1073Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50492154; called by muse, mutect2, varscan2
- DZIP3 | c.3379C>A p.Q1127K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV64312948; called by muse, mutect2, varscan2
- E4F1 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1174917633, COSV57040263; called by muse, mutect2, varscan2
- EDARADD | c.328C>A p.P110T (on ENST00000334232 / NM_145861.4; = p.P100T on NM_080738.4) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV62062207, COSV62063855; called by muse, mutect2, varscan2
- EEA1 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as COSV59288160; called by muse, mutect2, varscan2
- EFCAB1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as COSV50619159; called by muse, mutect2, varscan2
- ELAVL2 | c.789G>T p.L263F | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); catalogued as COSV56360719; called by muse, mutect2, varscan2
- ELP4 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV99540733; called by muse, mutect2
- ENPP2 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV50025254; called by muse, mutect2
- ENTR1 | c.970G>T p.V324F (on ENST00000357365 / NM_001039707.2; = p.V301F on NM_006643.4) | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53742488; called by muse, mutect2, varscan2
- EPC2 | c.2049G>C p.M683I | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.708); catalogued as COSV51546988; called by muse, mutect2
- EPHB1 | c.2243G>A p.R748K | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV67666373; called by muse, mutect2, varscan2
- EPHB3 | c.2412G>T p.W804C | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57807678; called by muse, mutect2, varscan2
- F13A1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53562967; called by muse, mutect2, varscan2
- FAM43A | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61673311; called by muse, mutect2, varscan2
- FAM47A | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.79); catalogued as rs1297774173, COSV60494660, COSV60498838; called by muse, mutect2, varscan2
- FAM71B | c.1736G>A p.G579D | Missense Mutation (SNP) | VAF 105/573 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1396828531, COSV57230087; called by muse, mutect2, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 33/141 reads (23%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FAT3 | c.12968C>T p.T4323I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781345146, COSV53146838; called by muse, mutect2, varscan2
- FBH1 | c.1305-1G>T p.X435_splice (on ENST00000362091 / NM_178150.3; = p.X486_splice on NM_032807.4) | Splice Site (SNP) | VAF 59/243 reads (24%) | catalogued as COSV62983681; called by muse, mutect2, varscan2
- FH | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.111); catalogued as rs201395553, CM125935, COSV63818617; called by muse, mutect2, varscan2
- FIBCD1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99446833; called by muse, mutect2
- FLNA | c.2860G>T p.D954Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61047873; called by muse, mutect2, varscan2
- FLNB | c.7416A>T p.T2472= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV55887539; called by muse, mutect2, varscan2
- FLT1 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV56731224, COSV56735070; called by muse, mutect2, varscan2
- FMOD | c.483C>A p.Y161* | Nonsense Mutation (SNP) | VAF 68/226 reads (30%) | catalogued as rs762821018, COSV61610405; called by mutect2, varscan2
- FOCAD | c.3450G>C p.M1150I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58104244; called by muse, mutect2
- FOXP4 | c.1015A>G p.T339A (on ENST00000307972 / NM_001012426.1; = p.T338A on NM_138457.3) | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV57222251; called by muse, mutect2, varscan2
- FRMD7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53747793; called by muse, mutect2, varscan2
- GAD1 | c.692A>T p.K231M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60153368; called by muse, mutect2, varscan2
- GCC2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59178412; called by muse, mutect2, varscan2
- GDF9 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs780122787, COSV51526444; called by muse, mutect2, varscan2
- GJA9 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 37/337 reads (11%) | catalogued as COSV62532544; called by muse, mutect2, varscan2
- GJB5 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100258313, COSV58356937; called by muse, mutect2, varscan2
- GLT8D1 | c.193_195del p.E65del | In Frame Del (DEL) | VAF 15/122 reads (12%) | catalogued as rs1285236528; called by pindel, varscan2
- GMPS | c.2075G>T p.W692L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55810830; called by muse, mutect2, varscan2
- GNAT3 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs768900454, COSV68068684; called by muse, mutect2, varscan2
- GOLIM4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.334); catalogued as COSV58330890; called by muse, varscan2
- GOLIM4 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs780290502, COSV58330898; called by muse, varscan2
- GPR158 | c.2723G>T p.S908I | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66276909; called by muse, mutect2, varscan2
- GPR158 | c.3417C>A p.H1139Q | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV66276914; called by muse, mutect2, varscan2
- GRK2 | c.1395G>T p.K465N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV57953034; called by muse, mutect2, varscan2
- GRK7 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV53824199; called by muse, mutect2, varscan2
- GRM4 | c.2333C>A p.P778H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65216343; called by muse, mutect2, varscan2
- GTDC1 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54000549; called by muse, mutect2, varscan2
- H1-5 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV58900817; called by muse, mutect2
- H2BU1 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); catalogued as rs776249694, COSV64209957; called by muse, mutect2, varscan2
- HADHB | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58547507; called by muse, mutect2, varscan2
- HAX1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.441); catalogued as COSV55172700; called by muse, mutect2
- HBG2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100400581; called by muse, mutect2, varscan2
- HBG2 | c.318C>A p.L106= | Splice Region (SNP) | VAF 38/138 reads (28%) | catalogued as COSV100400582; called by muse, mutect2, varscan2
- HDGFL3 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55207475; called by muse, mutect2, varscan2
- HIVEP2 | c.7304G>T p.S2435I | Missense Mutation (SNP) | VAF 49/477 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV50029009; called by muse, mutect2, varscan2
- HOXA5 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV56074174; called by muse, mutect2, varscan2
- HOXA5 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99762130; called by muse, mutect2, varscan2
- HOXB1 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53318040; called by muse, mutect2
- HS3ST2 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs768644712, COSV54465567; called by muse, mutect2, varscan2
- HSP90B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV55354988; called by muse, mutect2
- IFNA21 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs775971688, COSV66518611; called by muse, mutect2, varscan2
- IGF2BP1 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51733836; called by muse, mutect2
- IGKV3D-11 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as rs760083061; called by muse, mutect2
- IL12RB2 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs746456201, COSV52022463, COSV52025285; called by muse, mutect2, varscan2
- IL17F | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100277116; called by muse, mutect2, varscan2
- INSL5 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV58788429; called by muse, mutect2, varscan2
- INSYN1 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV101138691, COSV65837457; called by muse, mutect2, varscan2
- IQSEC1 | c.2797G>T p.G933W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56226543; called by muse, mutect2
- IQSEC2 | c.1733G>T p.C578F (on ENST00000642864 / NM_001111125.3; = p.C373F on NM_015075.2) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64727044; called by muse, mutect2, varscan2
- IRS2 | c.3736G>T p.G1246C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101018869; called by muse, mutect2, varscan2
- ITFG1 | c.1453G>C p.A485P | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV100278817, COSV57752388, COSV99076988; called by muse, mutect2, varscan2
- ITGB4 | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV52329736; called by muse, mutect2, varscan2
- ITPR2 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV101190066, COSV67273063; called by muse, mutect2, varscan2
- JAK1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV61094301; called by muse, mutect2, varscan2
- KALRN | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as COSV53762478, COSV53773546; called by muse, mutect2, varscan2
- KANSL1 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427624649, CM1513096, COSV52269520, COSV52271610; called by muse, mutect2, varscan2
- KCND2 | c.786G>C p.M262I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58593120; called by muse, mutect2, varscan2
- KCNK13 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56415189; called by muse, mutect2
- KIF2B | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52133413; called by muse, mutect2, varscan2
- KLHL32 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65113431; called by muse, mutect2, varscan2
- KLK7 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100304371; called by muse, mutect2, varscan2
- KLK8 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV99143898; called by muse, mutect2, varscan2
- KMT2A | c.10378G>C p.A3460P | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV63289826; called by muse, mutect2, varscan2
- KRT26 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV59415133; called by muse, mutect2, varscan2
- KRT73 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 26/157 reads (17%) | catalogued as COSV59837692, COSV59840769; called by muse, mutect2, varscan2
- LAMA1 | c.4157C>A p.P1386Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.532); catalogued as COSV67540597; called by muse, mutect2, varscan2
- LAMA4 | c.1486C>A p.L496I (on ENST00000230538 / NM_001105206.3; = p.L489I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as COSV57901682; called by muse, mutect2
- LAMB1 | c.4759G>C p.D1587H | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV55967790; called by muse, mutect2, varscan2
- LHFPL5 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs201197923, COSV100798939; called by muse, mutect2, varscan2
- LHFPL5 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as COSV100798940; called by muse, mutect2, varscan2
- LPAR4 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 79/409 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV70913063; called by muse, mutect2, varscan2
- LRFN5 | c.1696G>T p.V566F | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.56); catalogued as COSV53267606; called by muse, mutect2, varscan2
- LRMDA | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV65279071; called by muse, mutect2, varscan2
- LRP1B | c.3471C>A p.C1157* | Nonsense Mutation (SNP) | VAF 34/262 reads (13%) | catalogued as COSV101260962, COSV67250973; called by muse, mutect2, varscan2
- LRP8 | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV60100168; called by muse, mutect2, varscan2
- LRRC4B | c.270C>G p.Y90* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV101210163; called by muse, mutect2
- LRRC6 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 91/189 reads (48%) | catalogued as COSV51544947; called by muse, mutect2, varscan2
- LRRC7 | c.196G>C p.D66H (on ENST00000651989 / NM_001370785.2; = p.D33H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50525066; called by muse, mutect2, varscan2
- LRRFIP2 | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as COSV60869049; called by muse, mutect2, varscan2
- LTBP1 | c.2773C>A p.L925I (on ENST00000404816 / NM_206943.4; = p.L599I on NM_000627.4) | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.721); catalogued as COSV63193418; called by muse, mutect2, varscan2
- LYST | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV67710711; called by muse, mutect2, varscan2
- MAGEB1 | c.677T>G p.V226G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100974869; called by muse, mutect2, varscan2
- MAGEB3 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV64397473; called by muse, mutect2, varscan2
- MAGEL2 | c.2855C>A p.S952Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58568218; called by muse, mutect2, varscan2
- MAGI2 | c.1459G>C p.A487P | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV62681605; called by muse, mutect2, varscan2
- MAN1B1 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV65371661; called by muse, mutect2, varscan2
- MAP1A | c.7068T>A p.D2356E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.031); catalogued as COSV55811039; called by mutect2, varscan2
- MAP1B | c.1706C>A p.T569K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs754686684, COSV104393676, COSV57102987; called by muse, mutect2, varscan2
- MAP2 | c.1244T>A p.I415K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV52300078; called by muse, mutect2, varscan2
- MAP2K7 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209051, COSV67609125; called by muse, mutect2, varscan2
- MAP3K19 | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV59640788; called by muse, mutect2, varscan2
- MAP3K5 | c.2930G>T p.S977I | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100753205, COSV62890617; called by muse, mutect2, varscan2
- MAPK15 | c.1330-2A>T p.X444_splice | Splice Site (SNP) | VAF 11/106 reads (10%) | catalogued as rs201766090, COSV62029291; called by muse, mutect2, varscan2
- MAPT | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV52244018; called by muse, mutect2, varscan2
- MARCHF1 | c.229C>A p.Q77K (on ENST00000274056; = p.Q60K on NM_017923.4) | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV56818881, COSV99922290; called by muse, mutect2, varscan2
- MASTL | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60911758; called by muse, mutect2, varscan2
- MCM6 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918796; called by muse, mutect2
- MCM9 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV60164812; called by muse, mutect2, varscan2
- MCRS1 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV57791873, COSV99235423; called by muse, mutect2
- MCRS1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as COSV59460644, COSV99075983; called by muse, mutect2, varscan2
- MED12L | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV56388203; called by muse, mutect2, varscan2
- MEF2C | c.208A>C p.T70P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100424750; called by muse, mutect2, varscan2
- MID2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 21/145 reads (14%) | catalogued as COSV53311878; called by muse, mutect2, varscan2
- MLH3 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53135517; called by muse, mutect2, varscan2
- MLLT11 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV100927378; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1746A>T p.K582N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54915746; called by muse, mutect2, varscan2
- MPPED2 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63896032, COSV63899134, COSV63899956; called by muse, mutect2, varscan2
- MRC2 | c.1037G>A p.W346* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV57642342; called by muse, mutect2, varscan2
- MRGPRD | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as COSV100482947; called by muse, mutect2, varscan2
- MRGPRX4 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049651; called by muse, mutect2, varscan2
- MRPS35 | c.281del p.G94Afs*10 | Frame Shift Del (DEL) | VAF 55/156 reads (35%) | catalogued as COSV99317494; called by mutect2, pindel, varscan2
- MRS2 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV51234995; called by muse, mutect2, varscan2
- MUC16 | c.36304A>C p.T12102P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV67480157; called by muse, mutect2, varscan2
- MUC16 | c.35347A>T p.S11783C | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV67480160; called by muse, mutect2, varscan2
- MUC16 | c.5664G>T p.M1888I | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67480169; called by muse, mutect2, varscan2
- MUC17 | c.13187G>T p.G4396V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60296538; called by muse, mutect2, varscan2
- MUC5B | c.14738T>A p.L4913Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV71594244; called by muse, mutect2, varscan2
- MVP | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62422846; called by muse, mutect2
- MYEF2 | c.1144G>T p.G382W | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51050261; called by muse, mutect2, varscan2
- MYH7 | c.5071G>T p.V1691L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as CM031282, COSV62518813, COSV62521627; called by muse, mutect2, varscan2
- MYLK | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV60616169; called by muse, mutect2, varscan2
- MYO7A | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV68685964; called by muse, mutect2, varscan2
- MYOCD | c.2670G>T p.M890I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58502108, COSV58507935; called by muse, mutect2, varscan2
- MYRIP | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100218472, COSV56862009; called by muse, mutect2, varscan2
- NADSYN1 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59813741; called by muse, mutect2, varscan2
- NAPEPLD | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV58523324; called by muse, mutect2, varscan2
- NAV2 | c.5732T>C p.L1911S (on ENST00000396087 / NM_001244963.2; = p.L1852S on NM_145117.5) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60662353; called by muse, mutect2, varscan2
- NCAN | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53048935, COSV53054850; called by muse, mutect2, varscan2
- NDST4 | c.747C>A p.S249R | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV52128942; called by muse, mutect2, varscan2
- NDUFS7 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.19); catalogued as COSV99282632; called by mutect2, varscan2
- NEDD4 | c.2482G>T p.G828C (on ENST00000508342 / NM_001284338.1; = p.G409C on NM_006154.4) | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV59064317; called by muse, mutect2, varscan2
- NEURL4 | c.2409G>T p.W803C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100222744; called by muse, mutect2, varscan2
- NEURL4 | c.2408G>T p.W803L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV100222747; called by muse, mutect2, varscan2
- NEXN | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.585); catalogued as COSV57354969, COSV57359166; called by muse, mutect2, varscan2
- NIPBL | c.3063G>T p.E1021D | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99239243; called by muse, mutect2, varscan2
- NOTCH4 | c.3291C>A p.H1097Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as COSV100900870, COSV66682556; called by muse, mutect2, varscan2
- NPAP1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV61506881; called by muse, mutect2, varscan2
- NPAS3 | c.256A>T p.S86C (on ENST00000356141 / NM_001164749.2; = p.S56C on NM_022123.3) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV58097761; called by muse, mutect2, varscan2
- NPEPL1 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV61940076; called by muse, mutect2, varscan2
- NSRP1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV55934646; called by muse, mutect2, varscan2
- NTM | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66186891; called by muse, mutect2, varscan2
- NTRK3 | c.1889+1G>T p.X630_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV62310766; called by muse, varscan2
- NTRK3 | c.1577C>A p.P526Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58116820, COSV58127751; called by muse, mutect2
- NUDT13 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61969475; called by muse, mutect2, varscan2
- NXPE3 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56291215; called by muse, mutect2, varscan2
- OBSCN | c.1295T>G p.V432G | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99474229; called by muse, mutect2, varscan2
- OR10AG1 | c.389A>T p.K130I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV56633966; called by muse, mutect2, varscan2
- OR11H4 | c.304A>T p.I102F | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59560619; called by muse, mutect2, varscan2
- OR13G1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.148); catalogued as rs1270717816, COSV62944792; called by muse, mutect2, varscan2
- OR1J4 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61590089; called by muse, mutect2, varscan2
- OR2A25 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.216); catalogued as rs758409645, COSV68717469; called by muse, mutect2, varscan2
- OR2T11 | c.446del p.G149Afs*13 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | catalogued as rs758116021; called by mutect2, pindel, varscan2
- OR2T2 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61618598, COSV61618624; called by muse, mutect2
- OR4A15 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV59036483, COSV59036860; called by muse, mutect2, varscan2
- OR4K1 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV53461367; called by muse, mutect2, varscan2
- OR51V1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV58314037, COSV58315858; called by muse, mutect2, varscan2
- OR5M10 | c.293T>A p.F98Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV73242385; called by muse, mutect2, varscan2
- OR7G1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV53318331; called by muse, mutect2, varscan2
- OR8A1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV52507903, COSV52509280; called by muse, mutect2, varscan2
- OR8D2 | c.918G>T p.R306S | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62489081; called by muse, mutect2, varscan2
- OR8J3 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56882821; called by muse, mutect2, varscan2
- OTOGL | c.5015G>T p.R1672L (on ENST00000547103; = p.R1663L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/493 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs765255520, COSV100086838, COSV100087488; called by muse, mutect2, varscan2
- PAK5 | c.1134C>A p.H378Q | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV62033103; called by muse, mutect2, varscan2
- PAPPA2 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV62776206, COSV62782333; called by muse, mutect2, varscan2
- PAPPA2 | c.957A>T p.K319N | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62782341; called by muse, mutect2
- PAPPA2 | c.1111T>A p.Y371N | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62782350; called by muse, mutect2, varscan2
- PCDHA11 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV56487911, COSV56527538; called by muse, mutect2, varscan2
- PCDHA11 | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV56527562; called by muse, mutect2, varscan2
- PCDHB13 | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as COSV53398166, COSV53399071; called by muse, mutect2, varscan2
- PCDHB8 | c.2247C>A p.N749K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs782244145, COSV50794271; called by muse, mutect2, varscan2
- PCDHGA7 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV53992048; called by muse, mutect2
- PCDHGB1 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53992008; called by muse, mutect2, varscan2
- PCDHGB2 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53992028; called by muse, varscan2
- PCDHGB5 | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53992058; called by muse, mutect2
- PDE8A | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV59638971; called by muse, mutect2, varscan2
- PGGHG | c.2133C>G p.D711E | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV66888424; called by muse, mutect2, varscan2
- PHYHIPL | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV65849421; called by muse, mutect2, varscan2
- PIEZO2 | c.7856C>A p.S2619Y | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53292003, COSV99554305; called by muse, mutect2, varscan2
- PIEZO2 | c.6728C>G p.T2243S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53292026; called by muse, mutect2, varscan2
- PIP5K1B | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV55253123, COSV99598088; called by muse, mutect2, varscan2
- PIP5K1C | c.1807G>T p.G603C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs564190032, COSV58954307; called by muse, mutect2, varscan2
- PKHD1 | c.9751G>T p.E3251* | Nonsense Mutation (SNP) | VAF 87/202 reads (43%) | catalogued as COSV61887256; called by muse, mutect2, varscan2
- PLCB4 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53810430; called by muse, mutect2, varscan2
- PLCL1 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70843182, COSV70851373; called by muse, mutect2, varscan2
- PLD1 | c.1096G>C p.A366P | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100579077, COSV60571296; called by muse, mutect2, varscan2
- PNISR | c.502-2A>T p.X168_splice | Splice Site (SNP) | VAF 43/108 reads (40%) | catalogued as COSV65080096; called by muse, mutect2, varscan2
- PNLIP | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV65041363; called by muse, mutect2, varscan2
- POLR2D | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55758840; called by muse, mutect2
- POTEF | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as COSV62542533; called by muse, mutect2, varscan2
- PPM1B | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV56768440; called by muse, mutect2, varscan2
- PPP1R26 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV63356496; called by muse, mutect2, varscan2
- PRAMEF4 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 133/588 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV99339570; called by muse, varscan2
- PRPF38B | c.183G>C p.M61I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV64224206; called by muse, mutect2, varscan2
- PRPF38B | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.263); catalogued as rs1449202396, COSV64223694; called by muse, mutect2, varscan2
- PRPF40B | c.2285G>T p.R762L (on ENST00000380281; = p.R749L on NM_012272.3) | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53305229; called by muse, mutect2, varscan2
- PRRC2B | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1164682595, COSV61940631; called by muse, mutect2, varscan2
- PRRG3 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.708); catalogued as COSV64851322; called by muse, mutect2, varscan2
- PSG2 | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.541); catalogued as rs1287022778, COSV68885034; called by muse, mutect2, varscan2
- PSG9 | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52486673; called by muse, mutect2, varscan2
- PSMA7 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99443875; called by muse, mutect2, varscan2
- PTK7 | c.2970G>T p.W990C | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57850145; called by muse, mutect2, varscan2
- PTPRC | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 36/189 reads (19%) | catalogued as COSV61416842; called by muse, mutect2, varscan2
- PTPRD | c.3714+1G>T p.X1238_splice | Splice Site (SNP) | VAF 22/212 reads (10%) | catalogued as COSV61965873; called by muse, mutect2
- PTPRD | c.2749G>A p.V917I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs756674564, COSV61938116, COSV61965907; called by muse, mutect2, varscan2
- PTPRK | c.1696A>T p.T566S | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV63903079; called by muse, mutect2, varscan2
- PTPRR | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51739696; called by muse, mutect2, varscan2
- PTPRT | c.3538C>A p.Q1180K | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV61969777, COSV62000873, COSV62028893; called by muse, mutect2, varscan2
- PTPRT | c.1555T>A p.Y519N | Missense Mutation (SNP) | VAF 103/396 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100625691; called by muse, mutect2, varscan2
- PTPRT | c.1236C>A p.Y412* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV62000894; called by mutect2, varscan2
- PXK | c.388+1G>T p.X130_splice | Splice Site (SNP) | VAF 23/142 reads (16%) | catalogued as COSV57091286; called by muse, mutect2, varscan2
- RABGAP1L | c.1852G>T p.G618W | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311512; called by muse, mutect2, varscan2
- RABL3 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56337056; called by muse, mutect2, varscan2
- RAG1 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55026717; called by muse, varscan2
- RASAL2 | c.1768-1G>T p.X590_splice | Splice Site (SNP) | VAF 133/558 reads (24%) | catalogued as COSV62718560; called by muse, varscan2
- RGS1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV66505968; called by muse, mutect2, varscan2
- RGS20 | c.832G>A p.E278K (on ENST00000297313 / NM_170587.4; = p.E131K on NM_003702.4) | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV52020024; called by muse, mutect2, varscan2
- RNF185 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56736281; called by muse, mutect2, varscan2
- ROBO1 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.349); catalogued as COSV71396929; called by muse, mutect2, varscan2
- ROR2 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV65221791; called by muse, mutect2, varscan2
- RP1L1 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as COSV61446644; called by muse, mutect2, varscan2
- RPE65 | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52017372; called by muse, mutect2, varscan2
- RPLP0 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV56104812, COSV56111604; called by muse, mutect2, varscan2
- RREB1 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100619183; called by muse, varscan2
- RYR2 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as COSV63699999; called by muse, mutect2, varscan2
- RYR2 | c.5866G>T p.A1956S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV63700014; called by muse, mutect2, varscan2
- SAGE1 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 91/290 reads (31%) | catalogued as COSV61012804, COSV61015602; called by muse, mutect2, varscan2
- SAMD9 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV66076774; called by muse, mutect2
- SCN10A | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71862266; called by muse, mutect2, varscan2
- SCN3A | c.4367C>A p.S1456* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV51817544; called by muse, mutect2, varscan2
- SEMA5A | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66800304; called by muse, mutect2
- SEPTIN3 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52173268; called by muse, mutect2, varscan2
- SERPINA7 | c.93T>A p.H31Q | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV59666651; called by muse, mutect2, varscan2
- SF1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57116105, COSV57117845; called by muse, mutect2, varscan2
- SFRP4 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746754945, COSV71412371; called by muse, mutect2, varscan2
- SHC3 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65439650; called by muse, mutect2, varscan2
- SLC12A9 | c.1778A>G p.Q593R | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV51935478; called by muse, varscan2
- SLC22A11 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57254301; called by muse, mutect2, varscan2
- SLC22A16 | c.652-1G>T p.X218_splice | Splice Site (SNP) | VAF 44/119 reads (37%) | catalogued as COSV57932010; called by muse, mutect2, varscan2
- SLC2A9 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV53324740; called by muse, mutect2, varscan2
- SLC38A10 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55847406; called by muse, mutect2, varscan2
- SLC3A1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs121912696, CM941282, COSV53218101; called by muse, mutect2, varscan2
- SLC6A19 | c.1874C>T p.T625I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV57253027; called by muse, mutect2, varscan2
- SLIT3 | c.1759A>C p.M587L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60623091; called by muse, mutect2
- SLITRK4 | c.2313C>A p.S771R | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV62025314; called by muse, mutect2, varscan2
- SLITRK6 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV68390991; called by muse, mutect2, varscan2
- SMARCAL1 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV61922420; called by muse, mutect2, varscan2
- SORL1 | c.1361A>T p.Q454L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV52758526; called by muse, mutect2, varscan2
- SP4 | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99754121; called by muse, mutect2, varscan2
- SPAG6 | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV100510005; called by muse, mutect2, varscan2
- SPAG6 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1316504083, COSV100510009; called by muse, mutect2, varscan2
- SPATC1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1378912898, COSV66298565; called by muse, mutect2, varscan2
- STAB1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58740346; called by muse, mutect2, varscan2
- STAG3 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57932994; called by muse, mutect2, varscan2
- SULT1B1 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV60208588; called by muse, mutect2, varscan2
- SYNE1 | c.7029+1G>T p.X2343_splice (on ENST00000367255 / NM_182961.4; = p.X2350_splice on NM_033071.3) | Splice Site (SNP) | VAF 18/100 reads (18%) | catalogued as COSV55042619; called by muse, varscan2
- TAAR1 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 191/522 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.423); catalogued as COSV99257483; called by muse, mutect2, varscan2
- TAS2R16 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs752003332, COSV50797622; called by muse, mutect2, varscan2
- TAS2R30 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 78/182 reads (43%) | catalogued as COSV67859534; called by muse, mutect2, varscan2
- TBR1 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV67418603; called by muse, mutect2, varscan2
- TDO2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as rs1457249272, COSV70809438; called by muse, mutect2
- TEX15 | c.4592C>A p.T1531K (on ENST00000256246; = p.T1914K on NM_001350162.2) | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV56350171; called by muse, mutect2, varscan2
- TEX37 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV57556420; called by muse, mutect2, varscan2
- TGFB1I1 | c.548C>T p.P183L (on ENST00000394863 / NM_001042454.3; = p.P166L on NM_015927.4) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs757123886, COSV62358774; called by muse, mutect2
- THEG | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as rs1303006253, COSV61073709; called by muse, mutect2, varscan2
- THOC2 | c.4499G>T p.R1500L | Missense Mutation (SNP) | VAF 152/465 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV55542540, COSV55551282; called by muse, mutect2, varscan2
- TIAM2 | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59698946; called by muse, mutect2, varscan2
- TIE1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100992016; called by muse, mutect2, varscan2
- TJP1 | c.2019G>T p.K673N | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV62044194; called by muse, mutect2, varscan2
- TKTL2 | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 193/452 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV54920202; called by muse, mutect2, varscan2
- TMEFF1 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 16/163 reads (10%) | catalogued as COSV56867702; called by muse, mutect2
- TMEM267 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781542455, COSV67992463; called by muse, mutect2, varscan2
- TMTC1 | c.2474C>A p.A825D (on ENST00000539277 / NM_001193451.2; = p.A717D on NM_175861.3) | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55488076; called by muse, varscan2
- TMTC1 | c.1294T>A p.C432S (on ENST00000539277 / NM_001193451.2; = p.C324S on NM_175861.3) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as COSV55488084; called by muse, mutect2, varscan2
- TNC | c.4714C>A p.P1572T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV60787777; called by muse, mutect2, varscan2
- TNFRSF8 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99821161; called by muse, mutect2, varscan2
- TNR | c.2599C>A p.P867T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901103; called by muse, mutect2, varscan2
- TOP3A | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs144590444; called by muse, mutect2, varscan2
- TRAF3IP1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200967787, COSV64853579; called by muse, mutect2, varscan2
- TRAV17 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as rs780338637; called by muse, mutect2, varscan2
- TRHDE | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV53855616; called by muse, mutect2, varscan2
- TRIML1 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as COSV60195718; called by muse, mutect2, varscan2
- TRIO | c.3073A>T p.S1025C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60089102; called by muse, mutect2
- TRIP11 | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1409147252, COSV50940348; called by muse, mutect2, varscan2
- TRPC5 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV53297643; called by muse, mutect2, varscan2
- TRPM1 | c.3149G>T p.W1050L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56638489; called by muse, mutect2, varscan2
- TRPS1 | c.225G>T p.L75F (on ENST00000220888 / NM_001330599.2; = p.L88F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as rs764529424, COSV55252901; called by muse, mutect2, varscan2
- TRPV5 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54688054; called by muse, mutect2
- TSC2 | c.3542C>T p.T1181M | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.271); catalogued as rs373481458; ClinVar: uncertain significance / not provided; called by muse, varscan2
- TTC14 | c.753G>C p.M251I | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs752024603, COSV56013204; called by muse, mutect2, varscan2
- TTC17 | c.2416G>C p.G806R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50013649; called by muse, mutect2, varscan2
- TTF2 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | catalogued as COSV65633216; called by muse, mutect2, varscan2
- TTK | c.1522-1G>T p.X508_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as COSV57885383; called by muse, mutect2
- TTLL11 | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1401548651, COSV58649648; called by muse, mutect2, varscan2
- TTN | c.77344G>A p.E25782K (on ENST00000591111; = p.E18358K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | PolyPhen benign (0.003); catalogued as rs1486346584, COSV60206820; called by muse, mutect2, varscan2
- TTN | c.70030G>T p.A23344S (on ENST00000591111; = p.A15920S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | PolyPhen probably damaging (0.996); catalogued as rs878874875, COSV60206865; called by muse, mutect2, varscan2
- TUBB1 | c.843C>A p.Y281* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53887673, COSV53887684; called by muse, mutect2, varscan2
- TUBGCP6 | c.5108T>C p.V1703A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.336); catalogued as COSV50562672; called by muse, mutect2, varscan2
- UGT1A1 | c.1128T>A p.H376Q | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV59394085; called by muse, mutect2, varscan2
- UHRF2 | c.1453G>T p.G485W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99436235; called by muse, mutect2, varscan2
- UNC13C | c.4266G>A p.M1422I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV52901738; called by muse, mutect2
- UNC13C | c.6386G>T p.G2129V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs1304425603, COSV52901774; called by muse, mutect2, varscan2
- UNC93A | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV57809729; called by muse, mutect2
- URB2 | c.3431A>T p.D1144V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV51009531; called by muse, mutect2
- URB2 | c.3433A>T p.R1145W | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV51009938; called by muse, mutect2
- USP28 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV50173800; called by muse, mutect2, varscan2
- USP39 | c.1697G>C p.*566Sext*71 | Nonstop Mutation (SNP) | VAF 101/363 reads (28%) | catalogued as COSV60382611; called by muse, mutect2, varscan2
- USP48 | c.2303C>T p.S768L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as COSV57612479; called by muse, mutect2, varscan2
- UTP18 | c.741A>T p.E247D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV56584475; called by muse, mutect2, varscan2
- VCAN | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV54111316; called by muse, mutect2, varscan2
- VKORC1 | c.171C>A p.S57= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56232264; called by muse, mutect2, varscan2
- VWC2L | c.438C>A p.H146Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.61); catalogued as COSV56975015; called by muse, mutect2, varscan2
- WDFY3 | c.4201G>C p.V1401L | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55708733; called by muse, mutect2, varscan2
- WDR44 | c.1274+1G>C p.X425_splice | Splice Site (SNP) | VAF 36/101 reads (36%) | catalogued as COSV54166243; called by muse, mutect2, varscan2
- WDR7 | c.4447G>T p.G1483W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54358818; called by muse, mutect2, varscan2
- WHRN | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs587776360, COSV54332957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WSCD2 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV54587017, COSV99775137; called by muse, mutect2, varscan2
- XIRP2 | c.1408G>A p.E470K (on ENST00000628543; = p.E645K on NM_152381.6) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV54696955; called by muse, mutect2, varscan2
- ZDBF2 | c.3290G>T p.W1097L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV65628254; called by muse, mutect2, varscan2
- ZIC4 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV101267858; called by muse, mutect2, varscan2
- ZKSCAN7 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99837466; called by muse, mutect2, varscan2
- ZNF248 | c.1430C>G p.S477* | Nonsense Mutation (SNP) | VAF 88/256 reads (34%) | catalogued as COSV61997436, COSV61998145; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV71310222, COSV71312175, COSV71312346; called by muse, mutect2, varscan2
- ZNF385D | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 74/228 reads (32%) | catalogued as COSV55766004; called by muse, varscan2
- ZNF474 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV56945697; called by muse, mutect2, varscan2
- ZNF479 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV58641218; called by muse, mutect2, varscan2
- ZNF492 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV71762201; called by muse, mutect2, varscan2
- ZNF536 | c.3245G>T p.G1082V | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV62829434; called by muse, mutect2, varscan2
- ZNF681 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV101267405; called by muse, mutect2, varscan2
- ZNF701 | c.377C>T p.S126L (on ENST00000301093; = p.S60L on NM_018260.3) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.347); catalogued as rs867430381, COSV56526210; called by muse, mutect2, varscan2
- ZNF804A | c.3388C>A p.Q1130K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV56460202; called by muse, mutect2, varscan2
- ADAL | c.461dup p.L154Ffs*18 | Frame Shift Ins (INS) | VAF 66/216 reads (31%) | called by pindel, varscan2
- CARD8 | c.945_946delinsTAC p.S317Ffs*15 (on ENST00000651546 / NM_001184900.3; = p.S267Ffs*15 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 25/76 reads (33%) | called by pindel, varscan2*
- FREM1 | c.5337C>A p.V1779= | Splice Region (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- IFNAR2 | c.1539_1541del p.I513del | In Frame Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- IGHM | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 29/690 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.32); called by muse, mutect2
- IGKV1D-17 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- IGKV1D-17 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGKV1D-42 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- IGKV1D-8 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IGLC7 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITGAV | c.2371del p.E791Sfs*22 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- KAT6B | c.3022-15_3022del p.X1008_splice | Splice Site (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel
- KCNH1 | c.630del p.L211Yfs*15 | Frame Shift Del (DEL) | VAF 36/171 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.5038-13_5041del p.X1680_splice | Splice Site (DEL) | VAF 30/87 reads (34%) | called by mutect2, pindel
- KIR3DL3 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PPARGC1B | c.311del p.P104Lfs*102 | Frame Shift Del (DEL) | VAF 30/163 reads (18%) | called by mutect2, pindel, varscan2
- PTGIS | c.954del p.W318Cfs*18 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- SP110 | c.691del p.Q231Kfs*2 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- TPTE | c.839G>T p.R280L (on ENST00000618007 / NM_199261.4; = p.R262L on NM_199259.4) | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADAMTS1 | c.870C>A p.A290= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99535912; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1380G>C p.V460= | Silent (SNP) | VAF 45/295 reads (15%) | catalogued as COSV52820336, COSV52821547; called by muse, mutect2, varscan2
- AGL | c.1164C>G p.L388= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV54055869; called by muse, mutect2, varscan2
- ALX3 | c.312C>T p.P104= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100873868; called by muse, mutect2, varscan2
- AQP10 | c.93G>A p.V31= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV61475800; called by muse, mutect2, varscan2
- ARFIP1 | c.702C>A p.A234= (on ENST00000353617 / NM_001287432.1; = p.A202= on NM_014447.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV61885564; called by muse, mutect2, varscan2
- ASB15 | c.720G>T p.A240= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as COSV51927863; called by muse, mutect2, varscan2
- ATP2A1 | c.1966C>A p.R656= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs559067146, COSV62870272; called by muse, mutect2, varscan2
- BBS9 | c.354G>T p.G118= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV54178007; called by muse, mutect2
- BCL9L | c.4083C>T p.N1361= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV52687234; called by mutect2, varscan2
- C2orf76 | c.265C>T p.L89= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as COSV100601612; called by muse, mutect2
- CADPS | c.1170C>A p.S390= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV51892249; called by muse, mutect2, varscan2
- CDC42BPG | c.3471C>T p.L1157= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100711984; called by muse, mutect2, varscan2
- CDON | c.246G>T p.L82= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV55000371; called by muse, mutect2, varscan2
- CHAF1B | c.726C>T p.F242= | Silent (SNP) | VAF 163/384 reads (42%) | catalogued as COSV58440934; called by muse, mutect2, varscan2
- CHAT | c.522C>A p.G174= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs765982984, COSV100339848; called by muse, mutect2, varscan2
- CHD5 | c.1611G>T p.V537= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs771640708, COSV52420529; called by muse, mutect2, varscan2
- CKB | c.840C>T p.I280= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100818907; called by muse, mutect2, varscan2
- COL28A1 | c.150C>G p.V50= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV68083506, COSV68084686; called by muse, mutect2
- COL7A1 | c.930C>T p.L310= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV60399120; called by muse, varscan2
- CROCC | c.4533C>T p.L1511= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV65013688; called by muse, mutect2, varscan2
- CTHRC1 | c.213C>T p.A71= | Silent (SNP) | VAF 79/431 reads (18%) | catalogued as rs1275648002, COSV57715799; called by muse, mutect2, varscan2
- CTNNA2 | c.2019G>T p.A673= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV58166048, COSV58178978; called by muse, mutect2, varscan2
- CYP11B1 | c.288C>T p.D96= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs5284; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCHS1 | c.4668G>A p.E1556= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs201364249; called by muse, mutect2, varscan2
- DNAH11 | c.1074C>A p.R358= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV60967946; called by muse, mutect2, varscan2
- DNAH17 | c.11958C>T p.N3986= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs775593579, COSV67758597; called by muse, mutect2, varscan2
- DOCK10 | c.2985A>T p.A995= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV51421810; called by muse, mutect2
- DOCK8 | c.1524A>G p.L508= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs1305099911, COSV66634917; called by muse, mutect2, varscan2
- DSP | c.8277C>A p.R2759= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV100673079, COSV60940285; called by muse, mutect2, varscan2
- ECM2 | c.81G>A p.R27= | Silent (SNP) | VAF 31/169 reads (18%) | catalogued as COSV60742113; called by muse, mutect2, varscan2
- EEF2 | c.1641G>T p.A547= | Silent (SNP) | VAF 49/217 reads (23%) | catalogued as rs751031224, COSV58580193; called by muse, mutect2, varscan2
- EPG5 | c.3142C>T p.L1048= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as COSV56353177; called by muse, mutect2, varscan2
- FAM135B | c.3420C>T p.H1140= | Silent (SNP) | VAF 41/198 reads (21%) | catalogued as COSV52740540, COSV99428535; called by muse, mutect2, varscan2
- FBXL19 | c.195C>T p.P65= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs372946911; called by muse, mutect2
- FBXO31 | c.1350G>T p.V450= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100291299; called by muse, mutect2, varscan2
- FLG2 | c.5892C>A p.P1964= | Silent (SNP) | VAF 95/573 reads (17%) | catalogued as COSV66170979; called by muse, mutect2, varscan2
- FRY | c.4410T>A p.V1470= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV66574849; called by muse, mutect2, varscan2
- GOLGA3 | c.3513G>A p.K1171= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV52638004; called by muse, mutect2, varscan2
- GPNMB | c.1635C>T p.L545= (on ENST00000381990 / NM_001005340.2; = p.L533= on NM_002510.3) | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as rs1037972267, COSV51699665, COSV51700451; called by muse, mutect2, varscan2
- GPR149 | c.537C>T p.P179= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV67668700; called by muse, mutect2, varscan2
- GPR39 | c.18C>T p.L6= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs1405422133, COSV61425896; called by muse, mutect2, varscan2
- HCN3 | c.1086G>A p.E362= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV64234664; called by muse, mutect2, varscan2
- HOMER1 | c.639G>A p.Q213= | Silent (SNP) | VAF 47/282 reads (17%) | catalogued as COSV56526076; called by muse, mutect2, varscan2
- HOXA5 | c.126C>A p.S42= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV56072851; called by muse, mutect2, varscan2
- HS3ST1 | c.732G>A p.S244= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs745784456, COSV50023223; called by muse, mutect2, varscan2
- IER2 | c.219G>T p.P73= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99460103; called by muse, varscan2
- IGLV7-46 | c.349C>A p.R117= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- IGSF8 | c.1275C>T p.A425= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100081554; called by muse, mutect2, varscan2
- IL17F | c.207C>A p.S69= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100277120, COSV60235462; called by muse, mutect2, varscan2
- IL1F10 | c.285G>A p.E95= | Silent (SNP) | VAF 62/413 reads (15%) | catalogued as COSV61750839; called by muse, mutect2, varscan2
- INSR | c.609G>T p.G203= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV100251656; called by muse, mutect2, varscan2
- ITGA8 | c.2016C>T p.L672= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs1044612676, COSV65232537; called by muse, mutect2, varscan2
- ITGAM | c.1731C>T p.L577= (on ENST00000648685 / NM_001145808.2; = p.L576= on NM_000632.4) | Silent (SNP) | VAF 143/457 reads (31%) | catalogued as COSV54936571, COSV54939856; called by muse, mutect2, varscan2
- ITGAV | c.1047A>G p.L349= | Silent (SNP) | VAF 39/259 reads (15%) | catalogued as rs1323424402, COSV53716146; called by muse, mutect2, varscan2
- KALRN | c.60G>A p.L20= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV53773527; called by muse, mutect2, varscan2
- KCNH5 | c.2010G>C p.L670= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV59768194; called by muse, mutect2, varscan2
- KIR3DL3 | c.384C>A p.A128= | Silent (SNP) | VAF 92/268 reads (34%) | catalogued as COSV99399758; called by muse, mutect2, varscan2
- LINGO1 | c.592C>T p.L198= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs747637832, COSV62437829; called by muse, mutect2, varscan2
- LRAT | c.294C>A p.I98= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs558725765, COSV100312035; called by mutect2, varscan2
- LRRC32 | c.9C>A p.P3= | Silent (SNP) | VAF 41/211 reads (19%) | catalogued as rs1176955284, COSV52634291; called by muse, mutect2, varscan2
- LYNX1 | c.165C>T p.P55= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV100235461; called by muse, mutect2
- MAP1S | c.2274G>T p.A758= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV60722072, COSV60723648; called by muse, mutect2, varscan2
- MAPK3 | c.621G>T p.T207= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53775318; called by muse, mutect2, varscan2
- MGAT5 | c.567C>T p.L189= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs951757005, COSV56094820; called by muse, mutect2, varscan2
- MMP16 | c.192C>T p.R64= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs770768930, COSV54177821; called by muse, mutect2, varscan2
- MSGN1 | c.231G>T p.G77= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV55263362; called by muse, mutect2
- MSLN | c.1401G>T p.A467= (on ENST00000382862 / NM_013404.4; = p.A459= on NM_005823.6) | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV53504370; called by muse, mutect2, varscan2
- MUC16 | c.9753C>A p.A3251= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as COSV67480164; called by muse, mutect2, varscan2
- MUC6 | c.2436C>A p.G812= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV70144679, COSV70145339; called by muse, mutect2, varscan2
- MXRA5 | c.2868A>T p.T956= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV54243017; called by muse, mutect2, varscan2
- MYO5A | c.2622G>T p.R874= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV62562662; called by muse, mutect2, varscan2
- NDN | c.249G>T p.P83= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100086271, COSV59358953; called by muse, mutect2, varscan2
- NELL2 | c.1584C>A p.G528= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV61580694; called by muse, mutect2
- NLRP13 | c.2637G>T p.L879= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV61623160; called by muse, mutect2, varscan2
- NOS3 | c.1092G>A p.T364= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs144299379, COSV52492866; called by muse, mutect2
- NPVF | c.354G>A p.V118= | Silent (SNP) | VAF 42/315 reads (13%) | catalogued as rs750702117, COSV56061174; called by muse, varscan2
- NR5A2 | c.1551C>T p.L517= (on ENST00000367362 / NM_205860.3; = p.L471= on NM_003822.5) | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV52654162; called by muse, mutect2, varscan2
- NTSR1 | c.318C>A p.G106= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV65139141; called by muse, mutect2, varscan2
- OBSCN | c.1296G>T p.V432= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99474237; called by muse, mutect2, varscan2
- OR2AG1 | c.456A>G p.A152= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as rs924750560, COSV56626688; called by muse, mutect2
- OR4K5 | c.453G>C p.V151= | Silent (SNP) | VAF 123/1018 reads (12%) | catalogued as COSV60004384; called by muse, mutect2, varscan2
- OR5AR1 | c.558C>A p.A186= | Silent (SNP) | VAF 66/248 reads (27%) | catalogued as COSV57254592; called by muse, mutect2, varscan2
- OR5H15 | c.411C>A p.T137= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as COSV62948627; called by muse, mutect2, varscan2
- OR5M3 | c.597A>T p.I199= | Silent (SNP) | VAF 41/236 reads (17%) | catalogued as COSV56567893; called by muse, mutect2, varscan2
- OR5M8 | c.510C>A p.P170= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV59117562; called by muse, mutect2, varscan2
- OR6C76 | c.96G>T p.T32= | Silent (SNP) | VAF 73/279 reads (26%) | catalogued as COSV100093986, COSV60389553; called by muse, mutect2, varscan2
- OR6Y1 | c.216C>A p.S72= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV56930397; called by muse, mutect2, varscan2
- P4HA2 | c.735G>C p.G245= | Silent (SNP) | VAF 44/323 reads (14%) | catalogued as COSV51328556; called by muse, mutect2, varscan2
- PARP3 | c.264C>A p.L88= | Silent (SNP) | VAF 93/293 reads (32%) | catalogued as COSV51755542; called by muse, mutect2, varscan2
- PCDHA9 | c.2232G>C p.A744= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV65327272, COSV65329726; called by muse, mutect2, varscan2
- PCDHB11 | c.1071A>T p.P357= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV61313071; called by muse, mutect2, varscan2
- PCDHGA2 | c.2394C>A p.L798= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV53913549, COSV53991992; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1386C>T p.L462= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV62612697; called by muse, mutect2
- POLA2 | c.753C>T p.V251= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as rs1438494592, COSV55484814; called by muse, mutect2, varscan2
- POMZP3 | c.246C>T p.L82= | Silent (SNP) | VAF 19/298 reads (6%) | catalogued as rs774146612, COSV51887675; called by muse, mutect2
- PPP2R2B | c.378G>A p.R126= (on ENST00000394409; = p.R192= on NM_181674.2) | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV60771856; called by muse, mutect2, varscan2
- PRAMEF6 | c.606G>C p.V202= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100755814; called by mutect2, varscan2
- PRSS37 | c.327C>A p.A109= | Silent (SNP) | VAF 103/260 reads (40%) | catalogued as COSV63339823; called by muse, mutect2, varscan2
- PTPRT | c.1554C>A p.L518= | Silent (SNP) | VAF 103/396 reads (26%) | catalogued as COSV100625692; called by muse, mutect2, varscan2
- RAG2 | c.693C>A p.A231= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV57558736; called by muse, mutect2, varscan2
- RFX5 | c.741G>A p.K247= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV51840354; called by muse, mutect2, varscan2
- SCML2 | c.1155G>T p.P385= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as COSV52621967, COSV52623572; called by muse, mutect2, varscan2
- SCN11A | c.1060C>A p.R354= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV56574301; called by muse, mutect2, varscan2
- SERPING1 | c.1494C>T p.P498= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV53543599, COSV99558108; called by muse, mutect2
- SHC1 | c.723C>T p.L241= (on ENST00000368445 / NM_183001.5; = p.L131= on NM_003029.5) | Silent (SNP) | VAF 145/552 reads (26%) | catalogued as COSV63535031; called by muse, mutect2, varscan2
- SHLD2 | c.60C>T p.I20= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV53957046; called by muse, mutect2, varscan2
- SHROOM4 | c.3684G>A p.E1228= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV56793554; called by muse, mutect2, varscan2
- SI | c.2868A>T p.T956= | Silent (SNP) | VAF 68/282 reads (24%) | catalogued as COSV52290507; called by muse, mutect2, varscan2
- SLC10A7 | c.168A>T p.L56= | Silent (SNP) | VAF 241/576 reads (42%) | catalogued as COSV53887574; called by muse, mutect2, varscan2
- SLC6A14 | c.1914C>T p.S638= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV64141294; called by muse, mutect2, varscan2
- SLC9C1 | c.1497T>C p.C499= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV59890588; called by muse, mutect2, varscan2
- SLFN12 | c.1251C>T p.V417= | Silent (SNP) | VAF 49/243 reads (20%) | catalogued as rs112295255, COSV59226900; called by muse, mutect2, varscan2
- SMARCD1 | c.1320C>T p.F440= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV67412685; called by muse, mutect2, varscan2
- ST18 | c.12G>A p.E4= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as rs1033279447, COSV52502069; called by muse, mutect2, varscan2
- SYNE1 | c.14751G>T p.L4917= (on ENST00000367255 / NM_182961.4; = p.L4846= on NM_033071.3) | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as rs769489729, COSV55042583; called by muse, mutect2, varscan2
- TACC2 | c.3192G>A p.A1064= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs936063133, COSV57764611; called by muse, mutect2, varscan2
- TFIP11 | c.1710C>T p.I570= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs747972427, COSV53227038; called by muse, mutect2, varscan2
- THBS2 | c.2520G>T p.L840= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV64680897; called by muse, mutect2, varscan2
- TIMD4 | c.234A>T p.S78= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV50857616; called by muse, mutect2, varscan2
- TMPRSS2 | c.276G>C p.G92= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100152149, COSV59825349; called by muse, mutect2, varscan2
- TNFRSF8 | c.99C>A p.P33= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as COSV99821163; called by muse, mutect2, varscan2
- TP53RK | c.297A>T p.P99= | Silent (SNP) | VAF 163/574 reads (28%) | catalogued as COSV64509091; called by muse, mutect2, varscan2
- TRAPPC9 | c.2061A>T p.T687= | Silent (SNP) | VAF 105/181 reads (58%) | catalogued as COSV66905154; called by muse, mutect2, varscan2
- TRIM50 | c.1149C>T p.G383= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs782146377, COSV53092925; called by muse, varscan2
- TRPM3 | c.4560C>A p.P1520= (on ENST00000357533 / NM_001366142.2; = p.P1375= on NM_020952.6) | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100676790; called by muse, mutect2, varscan2
- TSKS | c.975C>G p.T325= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs762305803, COSV99882985; called by muse, mutect2, varscan2
- UGGT1 | c.552C>T p.H184= | Silent (SNP) | VAF 41/441 reads (9%) | catalogued as COSV52138964; called by muse, mutect2, varscan2
- USH2A | c.5274C>T p.N1758= | Silent (SNP) | VAF 76/296 reads (26%) | catalogued as rs933035458, COSV56403364, COSV56403459; called by muse, mutect2, varscan2
- VANGL1 | c.378C>T p.T126= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as rs756440560, COSV59621485; called by muse, mutect2, varscan2
- VAV3 | c.2343C>A p.G781= | Silent (SNP) | VAF 81/284 reads (29%) | catalogued as COSV100579272; called by muse, mutect2, varscan2
- VCP | c.1317C>T p.A439= | Silent (SNP) | VAF 56/464 reads (12%) | catalogued as rs1009713233, COSV62721553; called by muse, mutect2, varscan2
- ZFPM2 | c.3255T>A p.A1085= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV65874826; called by muse, mutect2
- ZFYVE26 | c.6735A>G p.L2245= | Silent (SNP) | VAF 201/542 reads (37%) | catalogued as COSV61331389; called by muse, mutect2, varscan2
- ZNF536 | c.129C>T p.L43= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV62829426; called by muse, mutect2
- ZNF827 | c.1683G>T p.A561= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as COSV65226025, COSV65229761; called by muse, mutect2, varscan2
- ZSCAN26 | c.891C>T p.L297= (on ENST00000623276 / NM_001111039.2; = p.L163= on NM_152736.5) | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs374282195; called by muse, mutect2, varscan2
- ACP1 | c.231+132C>T | Intron (SNP) | VAF 20/58 reads (34%) | catalogued as rs1457080362, COSV55244375; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700963 C>G | 3'Flank (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- ENPP2 | c.973-2113G>T | Intron (SNP) | VAF 122/261 reads (47%) | catalogued as COSV99307698; called by muse, mutect2, varscan2
- ITPRID2 | c.*63G>T | 3'UTR (SNP) | VAF 36/255 reads (14%) | catalogued as COSV100237965; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397708 G>A | 3'Flank (SNP) | VAF 22/200 reads (11%) | catalogued as rs1327486428; called by muse, mutect2, varscan2
- MIR516B1 | n.47G>C | RNA (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- RUBCNL | c.-122-5316C>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100528888; called by mutect2, varscan2
- SUN1 | c.659-1451C>T | Intron (SNP) | VAF 65/263 reads (25%) | catalogued as COSV100568566; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580396 G>A | 3'Flank (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- ZNF322P1 | n.200G>T | RNA (SNP) | VAF 86/512 reads (17%) | called by muse, mutect2, varscan2
